Somatic mutation profile of tumor specimen 0DPOKV from CCDI case PBCEAF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.1 years (5,133 days).
Specimen 0DPOKV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3099cbb0-d29f-44d0-9eb7-9f1e5897a1c8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPOKT (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7413498a-e0db-4334-963f-53ee75594536

The open-access MAF lists 43 somatic variants for this specimen: 27 protein-altering or splice-affecting, 9 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 9, Intron 4, 5'UTR 2, Splice Site 2, Frame Shift Del 2, 3'UTR 1, In Frame Del 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.4190G>A p.W1397* | Nonsense Mutation (SNP) | VAF 144/830 reads (17%) | catalogued as rs886037711; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FGFR1 | c.1638C>A p.N546K (on ENST00000447712 / NM_023110.3; = p.N544K on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 147/320 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779707422, COSV58329537, COSV58330551; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.673-1G>C p.X225_splice | Splice Site (SNP) | VAF 136/138 reads (99%) | hotspot (GDC flag); catalogued as CS011061, COSV52662773, COSV52705331, COSV52707963, COSV53154363; called by muse, mutect2, varscan2
- AKR1C3 | c.454G>C p.E152Q | Missense Mutation (SNP) | VAF 36/284 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101003185, COSV65911302; called by mutect2, varscan2
- CCDC168 | c.9613A>G p.I3205V | Missense Mutation (SNP) | VAF 34/575 reads (6%) | SIFT tolerated (0.75); PolyPhen benign (0.11); catalogued as rs940386613; called by muse, mutect2
- DICER1 | c.5426G>A p.G1809E | Missense Mutation (SNP) | VAF 287/407 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58626659; called by muse, mutect2, varscan2
- DICER1 | c.5425G>A p.G1809R | Missense Mutation (SNP) | VAF 287/407 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58615244, COSV58615703, COSV58615881; called by muse, mutect2, varscan2
- OR6N2 | c.381T>G p.C127W | Missense Mutation (SNP) | VAF 17/562 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100210570; called by muse, mutect2
- RIMS2 | c.1139A>T p.D380V (on ENST00000666250 / NM_001348490.2; = p.D188V on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/702 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); catalogued as rs1304643498; called by muse, mutect2
- SGK1 | c.260C>G p.P87R | Missense Mutation (SNP) | VAF 302/674 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.629); catalogued as rs764600523; called by muse, mutect2, varscan2
- AGBL4 | c.237C>A p.F79L | Missense Mutation (SNP) | VAF 54/1300 reads (4%) | SIFT tolerated (0.35); PolyPhen benign (0.031); called by muse, mutect2
- C1QTNF4 | c.788C>G p.A263G | Missense Mutation (SNP) | VAF 12/324 reads (4%) | SIFT tolerated (0.38); PolyPhen benign (0.012); called by muse, mutect2
- CRTC2 | c.1999G>A p.G667R | Missense Mutation (SNP) | VAF 161/311 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FASTKD3 | c.1564C>G p.L522V | Missense Mutation (SNP) | VAF 198/528 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- FBXO41 | c.1861A>G p.N621D | Missense Mutation (SNP) | VAF 36/636 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- LMO7 | c.3796G>A p.V1266I (on ENST00000357063; = p.V947I on NM_005358.5) | Missense Mutation (SNP) | VAF 28/264 reads (11%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.82); called by mutect2, varscan2
- MARK2 | c.988+2T>C p.X330_splice | Splice Site (SNP) | VAF 26/404 reads (6%) | called by muse, mutect2
- MDC1 | c.389A>G p.Y130C | Missense Mutation (SNP) | VAF 205/383 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NAT9 | c.295_299del p.E99Pfs*18 | Frame Shift Del (DEL) | VAF 88/260 reads (34%) | called by mutect2, varscan2
- OR5V1 | c.901G>T p.V301F | Missense Mutation (SNP) | VAF 64/724 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2
- PCDH15 | c.1510G>T p.D504Y | Missense Mutation (SNP) | VAF 272/574 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTK2B | c.2510A>G p.D837G | Missense Mutation (SNP) | VAF 156/333 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCUBE1 | c.101_105del p.V34Gfs*8 | Frame Shift Del (DEL) | VAF 106/114 reads (93%) | called by mutect2, varscan2
- SLC25A30 | c.478_480del p.G160del | In Frame Del (DEL) | VAF 78/273 reads (29%) | called by mutect2, varscan2
- TMEM259 | c.1732C>T p.H578Y | Missense Mutation (SNP) | VAF 91/124 reads (73%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TRIML1 | c.206A>T p.E69V | Missense Mutation (SNP) | VAF 134/225 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- UBR1 | c.4745dup p.N1582Kfs*8 | Frame Shift Ins (INS) | VAF 57/465 reads (12%) | called by mutect2, varscan2
- ALDH18A1 | c.2196C>T p.R732= | Silent (SNP) | VAF 250/461 reads (54%) | called by muse, mutect2
- CCNF | c.2271G>A p.E757= | Silent (SNP) | VAF 116/209 reads (56%) | catalogued as rs1039034118; called by muse, mutect2, varscan2
- EPHA5 | c.108A>G p.R36= | Silent (SNP) | VAF 116/211 reads (55%) | called by muse, mutect2, varscan2
- FAM83B | c.2302T>C p.L768= | Silent (SNP) | VAF 60/680 reads (9%) | called by muse, mutect2
- FRA10AC1 | c.363C>T p.D121= | Silent (SNP) | VAF 40/515 reads (8%) | catalogued as rs929811512, COSV63271107; called by muse, mutect2
- PIP5K1A | c.222G>A p.E74= (on ENST00000368888 / NM_001135638.2; = p.E61= on NM_003557.3) | Silent (SNP) | VAF 103/253 reads (41%) | catalogued as COSV100576471; called by muse, mutect2, varscan2
- PTPRS | c.1998G>A p.P666= | Silent (SNP) | VAF 78/85 reads (92%) | catalogued as rs534493089, COSV53610154, COSV53613238, COSV53626630; called by muse, mutect2, varscan2
- TMEM176A | c.546C>T p.D182= | Silent (SNP) | VAF 30/588 reads (5%) | called by muse, mutect2
- UBA7 | c.1918C>T p.L640= | Silent (SNP) | VAF 18/620 reads (3%) | catalogued as COSV100323720; called by muse, mutect2
- BAZ2B | c.1293+82A>G | Intron (SNP) | VAF 29/69 reads (42%) | called by mutect2, varscan2
- HINT2 | c.222+16G>T | Intron (SNP) | VAF 88/299 reads (29%) | called by muse, mutect2, varscan2
- HMOX1 | c.-78A>C | 5'UTR (SNP) | VAF 16/90 reads (18%) | called by muse, mutect2
- ILDR2 | c.*28G>A | 3'UTR (SNP) | VAF 150/338 reads (44%) | catalogued as COSV99613583; called by muse, mutect2, varscan2
- RPS16 | c.296-14G>A | Intron (SNP) | VAF 35/161 reads (22%) | called by muse, varscan2
- TRIM63 | c.-81C>A | 5'UTR (SNP) | VAF 16/71 reads (23%) | called by muse, mutect2, varscan2
- UBE2Q2 | c.180+652G>A | Intron (SNP) | VAF 13/226 reads (6%) | called by muse, mutect2
